Somatic mutation profile of tumor specimen TCGA-EJ-5501-01A (aliquot TCGA-EJ-5501-01A-01D-1576-08) from TCGA case TCGA-EJ-5501, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,409 days).
Specimen TCGA-EJ-5501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b967c83d-6cb7-4869-977c-d11cd3cfcd69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5501-10A (Blood Derived Normal), aliquot TCGA-EJ-5501-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/283a33f0-1421-469a-b596-0f93a823e951

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as rs757459157, COSV64601838; called by muse, mutect2
- AKAP3 | c.1774A>G p.S592G | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV57421317; called by muse, mutect2, varscan2
- ANKH | c.1472A>G p.N491S | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52486923; called by muse, mutect2, varscan2
- CD8A | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770405273, COSV52159672; called by muse, mutect2, varscan2
- CLEC18B | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs763795298, COSV60579046; called by muse, mutect2
- CTNNAL1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57705770; called by muse, mutect2, varscan2
- FAM153A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.502); catalogued as rs143733594, COSV62362183; called by muse, mutect2, varscan2
- GPR78 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs765821153, COSV66764106; called by muse, mutect2, varscan2
- MCC | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200082888, COSV56730608; called by muse, mutect2, varscan2
- NBPF3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1371681269, COSV59065252; called by muse, mutect2, varscan2
- PICK1 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.357); catalogued as COSV63662164; called by muse, mutect2, varscan2
- TMC3 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369492533; called by muse, mutect2, varscan2
- TRARG1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61563388; called by muse, mutect2
- VPS13C | c.6837_6839del p.V2280del (on ENST00000644861 / NM_020821.3; = p.V2237del on NM_017684.5) | In Frame Del (DEL) | VAF 24/169 reads (14%) | catalogued as rs1442965578; called by pindel, varscan2
- CHGA | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIX1 | c.849dup p.S284Vfs*22 | Frame Shift Ins (INS) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- TBC1D13 | c.240del p.Q80Hfs*16 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- TBX3 | c.1097_1098del p.K366Rfs*8 (on ENST00000257566 / NM_016569.4; = p.K346Rfs*8 on NM_005996.4) | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, varscan2
- CCDC127 | c.594C>T p.P198= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs372308365, COSV57258177; called by muse, mutect2, varscan2
- DNMT3A | c.1689G>A p.V563= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1432188950, COSV53080433; called by muse, mutect2, varscan2
- GLI2 | c.3144C>T p.D1048= (on ENST00000361492 / NM_001374353.1; = p.D1065= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1257064803, COSV58052160; called by muse, mutect2
- IRX2 | c.651C>T p.D217= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV57413969; called by muse, mutect2
- TUBA3D | c.357G>C p.L119= | Silent (SNP) | VAF 31/234 reads (13%) | catalogued as COSV58313477; called by muse, mutect2, varscan2
